Gene-level copy-number profile of tumor specimen TCGA-2J-AABK-01A from TCGA case TCGA-2J-AABK, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 71.7 years (26,188 days).
Specimen TCGA-2J-AABK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.82b36343-4d0d-4ef1-ade8-cf43e1a2ead7.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2J-AABK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 388 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS.
https://portal.gdc.cancer.gov/files/133e3753-6e40-4b02-8fea-bec1727c558b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,751; copy number 1: 7,546; copy number 2: 46,002; copy number 3: 2,454; copy number 4: 326; copy number 5: 1,057; copy number 6: 1; copy number 11: 1; copy number 12: 97.

Homozygous deletions (total copy number 0; autosomes only): 344 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:64,450,096–64,461,381, 2 genes (within-gene range 0–2): AC008074.1, LGALSL.
- chr3:27,110,085–27,369,460, 3 genes (within-gene range 0–2): NEK10, MICOS10P3, RNU6-342P.
- chr3:151,797,047–151,828,488, 2 genes (within-gene range 0–2): AC068647.2, AADAC.
- chr6:30,414,715–30,792,250, 30 genes: MICC, AL662873.1, TMPOP1, SUCLA2P1, RANP1, HLA-E, LINC02569, GNL1, PRR3, ABCF1, MIR877, PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P.
- chr11:58,387,583–58,388,486, 1 gene: OR5B15P.
- chr17:41,265,339–41,271,835, 2 genes: KRTAP9-6, KRTAP9-11P.
- chr17:46,193,576–46,215,171, 2 genes: KANSL1-AS1, Y_RNA.
- chr18:59,430,939–59,697,662, 1 gene (within-gene range 0–1): CCBE1.
- chr18:59,563,709–80,247,514, 299 genes (broad region; genes not listed).
- chr20:24,679,547–24,932,983, 2 genes: AL049594.1, AL035661.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,156 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–167,427,345, 943 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:181,317,690–187,686,628, 111 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:124,151,923–124,152,433, 1 gene, copy number 11: ARF1P3.
- chr10:93,881,293–93,961,540, 3 genes, copy number 5: RAB11AP1, SLC35G1, PIPSL.
- chr14:105,785,505–106,344,833, 97 genes, copy number 12 (broad region; genes not listed).
- chr17:73,737,854–73,756,932, 1 gene, copy number 6 (within-gene range 3–6): AC125421.1.

Autosomal genes at a single copy (total copy number 1): 7,023. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
